Gene-level copy-number profile of tumor specimen HTMCP-02-03-01016-01A from CGCI case HTMCP-02-03-01016, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.6 years (19,939 days).
Specimen HTMCP-02-03-01016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a1124dde-79db-42e6-a84d-c6ba082d995f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-03-01016-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/5295d98b-c210-45b0-9598-66348cf097c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 48,387; copy number 3: 9,774; copy number 4: 181; copy number 5: 31; copy number 6: 7; copy number 7: 2; copy number 8: 1; copy number 18: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 44 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:206,147,164–206,464,443, 6 genes, copy number 5: AC244035.4, RPL22P4, AC244035.2, FAM72A, SRGAP2, AC244023.1.
- chr4:49,203,171–49,246,915, 7 genes, copy number 5: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr7:63,326,674–63,359,306, 7 genes, copy number 6 (within-gene range 6–7): AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4.
- chr7:74,773,962–74,913,310, 6 genes, copy number 5: NCF1, GTF2IRD2, STAG3L2, PMS2P5, Y_RNA, SPDYE12P.
- chr9:64,817,870–64,836,341, 1 gene, copy number 7: AL359955.1.
- chr10:47,908,064–47,991,877, 3 genes, copy number 18: AC245041.2, NPY4R2, AC245041.1.
- chr10:48,009,873–48,040,577, 2 genes, copy number 5: AGAP12P, RNA5SP315.
- chr15:28,402,868–28,405,033, 1 gene, copy number 5: ABCB10P3.
- chr15:30,135,149–30,179,943, 5 genes, copy number 5: GOLGA8T, RN7SL469P, DNM1P30, AC120045.2, AC120045.1.
- chr15:30,516,079–30,545,969, 2 genes, copy number 5: AC026150.2, AC026150.1.
- chr16:32,600,299–32,615,639, 1 gene, copy number 7: AC137800.1.
- chr17:46,372,855–46,487,141, 1 gene, copy number 8: NSFP1.
- chr18:11,619,509–11,639,699, 2 genes, copy number 5: NPIPB1P, AP001120.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
